Somatic mutation profile of tumor specimen TCGA-DJ-A1QD-01A (aliquot TCGA-DJ-A1QD-01A-11D-A14W-08) from TCGA case TCGA-DJ-A1QD, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 20.4 years (7,460 days).
Specimen TCGA-DJ-A1QD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92830b88-086d-47e4-9a88-394189da2f7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A1QD-10A (Blood Derived Normal), aliquot TCGA-DJ-A1QD-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56b8cb36-0dc0-449a-814d-24745d6f2860

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACAN | c.5851G>A p.A1951T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.646); catalogued as COSV61355083; called by muse, mutect2, varscan2
- AMPD2 | c.1139T>C p.I380T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56645944; called by muse, mutect2, varscan2
- FRMPD3 | c.1689C>A p.Y563* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99346300; called by muse, mutect2, varscan2
- RIC1 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV52604328; called by muse, mutect2
- SPINK9 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.393); catalogued as rs762331307, COSV64957820; called by muse, mutect2, varscan2
- TMEM176B | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs141592438, COSV50240252; called by muse, mutect2, varscan2
